Gene-level copy-number profile of tumor specimen TARGET-10-PASKRN-03A from TARGET case TARGET-10-PASKRN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,895 days).
Specimen TARGET-10-PASKRN-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.d6109f82-f9c9-5e69-8772-62928954edad.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASKRN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 401 have no estimate.
https://portal.gdc.cancer.gov/files/48e1dd2a-90e8-4317-b14a-0a2465633c9e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,456; copy number 1: 920; copy number 2: 56,073; copy number 3: 540; copy number 4: 201; copy number 6: 32.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:285,443–292,013, 1 gene: AL365272.1.
- chr7:38,256,337–38,318,861, 10 genes (within-gene range 0–2): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr8:38,996,754–39,730,065, 8 genes (within-gene range 0–2): ADAM9, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18.
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–1): MIR31HG.
- chr9:21,512,115–24,592,104, 38 genes: MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1.
- chr14:22,415,362–22,477,769, 15 genes: AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58.
- chr15:91,676,771–91,677,060, 1 gene: AC107958.1.
- chr21:32,538,299–32,538,434, 1 gene: AP000272.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes, copy number 6: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr10:45,706,431–46,537,864, 25 genes, copy number 6 (within-gene range 2–6): FAM21FP, AL645998.1, WASHC2C, AC012044.1, FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4, MSMB, RPL23AP61, AGAP7P, ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R.
- chr11:4,954,772–4,955,713, 1 gene, copy number 6: OR51A2.

Autosomal genes at a single copy (total copy number 1): 913. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
